Gene-level copy-number profile of tumor specimen TCGA-75-6211-01A from TCGA case TCGA-75-6211, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-6211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ca9e17f5-c828-4b3a-a85a-65c5b2a21ca0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-6211-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d22a2646-023c-440a-b474-3e93572b4271

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,519; copy number 2: 14,402; copy number 3: 19,792; copy number 4: 16,768; copy number 5: 5,519; copy number 6: 1,475; copy number 7: 234; copy number 12: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-6211-01A-11D-1752-01): tumor purity 0.39, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 341 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:35,632,659–40,134,622, 106 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).
- chr7:40,151,613–40,154,151, 1 gene, copy number 12: THUMPD3P1.
- chr7:54,542,325–62,275,678, 154 genes, copy number 7 (broad region; genes not listed).
- chr8:127,578,473–129,683,770, 24 genes, copy number 7 (within-gene range 4–7): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr11:28,986,635–29,266,734, 2 genes, copy number 7: OR2BH1P, AC090791.1.
- chr12:11,391,540–12,562,863, 26 genes, copy number 7 (within-gene range 4–7): PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1.
- chr20:47,950,797–49,278,426, 28 genes, copy number 7 (within-gene range 4–7): AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1.

Autosomal genes at a single copy (total copy number 1): 1,519. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
